Gene-level copy-number profile of tumor specimen TCGA-DX-A3LT-01A from TCGA case TCGA-DX-A3LT, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 62.5 years (22,837 days).
Specimen TCGA-DX-A3LT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.8f96eddc-fd74-4bca-9539-fdd866750bf4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A3LT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5c0bd832-ef9f-40a8-abbc-34941bcfe091

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,846; copy number 2: 23,229; copy number 3: 17,671; copy number 4: 16,123; copy number 5: 152; copy number 6: 279; copy number 8: 28; copy number 9: 11; copy number 11: 4; copy number 12: 48; copy number 13: 1; copy number 14: 78; copy number 15: 2; copy number 16: 4; copy number 17: 1; copy number 18: 1; copy number 19: 2; copy number 20: 7; copy number 21: 13; copy number 23: 8; copy number 24: 30; copy number 25: 12; copy number 27: 2; copy number 28: 16; copy number 29: 1; copy number 30: 46; copy number 32: 2; copy number 34: 7; copy number 35: 8; copy number 36: 2; copy number 37: 23; copy number 38: 3; copy number 40: 7; copy number 42: 8; copy number 43: 20; copy number 46: 2; copy number 47: 1; copy number 48: 32; copy number 49: 45; copy number 50: 6; copy number 51: 1; copy number 54: 1; copy number 57: 1; copy number 58: 1; copy number 59: 2; copy number 60: 7; copy number 82: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A3LT-01A-12D-A21P-01): tumor purity 0.77, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:20,574,186–21,575,686, 10 genes (within-gene range 0–2): HMGB1P40, AC090707.2, SLC6A5, NELL1, AC090707.1, RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337.
- chr11:24,496,970–25,082,638, 2 genes (within-gene range 0–16): LUZP2, AC115990.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 931 genes in 54 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:140,865,075–141,926,549, 28 genes, copy number 8: AC121333.1, RPL23AP41, SLC25A36, AC108727.1, SPSB4, AC108727.2, PXYLP1, AC022215.2, AC022215.1, AC117383.1, AC117383.2, ZBTB38, AC010184.1, KRT18P35, RASA2, RASA2-IT1, YWHAQP6, LINC02618, TPT1P3, AC112771.1, RNF7, AC112504.2, GRK7, AC112504.3, HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1.
- chr3:169,447,867–170,181,749, 27 genes, copy number 5–14 (within-gene range 2–14): MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3.
- chr5:23,443,586–23,528,093, 2 genes, copy number 9 (within-gene range 2–9): PRDM9, AC109445.1.
- chr5:31,093,977–32,444,740, 34 genes, copy number 6–12 (within-gene range 2–12): AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579.
- chr10:90,622,143–90,623,611, 1 gene, copy number 58: AL390862.1.
- chr11:1,012,823–2,141,238, 53 genes, copy number 14: MUC6, LINC02688, MUC2, MUC5AC, AC061979.1, MUC5B, MUC5B-AS1, MIR6744, TOLLIP, TOLLIP-AS1, AC136297.1, LINC02689, BRSK2, AC091196.1, MOB2, DUSP8, KRTAP5-AS1, KRTAP5-1, KRTAP5-2, KRTAP5-3, KRTAP5-4, KRTAP5-5, AP006285.1, FAM99A, FAM99B, LINC02708, KRTAP5-6, IFITM10, AC068580.4, CTSD, AC068580.3, AC068580.1, AC068580.5, AC068580.2, RPL36AP39, AC139143.1, SYT8, TNNI2, LSP1, MIR4298, AC051649.1, MIR7847, PRR33, LINC01150, TNNT3, MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2, IGF2.
- chr11:2,376,177–2,992,377, 21 genes, copy number 12: CD81, TSSC4, AC124057.1, TRPM5, KCNQ1, KCNQ1OT1, AC021424.1, AC021424.3, AC021424.4, AC021424.2, COX6CP18, KCNQ1-AS1, KCNQ1DN, AC013791.1, CDKN1C, SLC22A18AS, SLC22A18, PHLDA2, NAP1L4, SNORA54, AC131971.1.
- chr11:13,054,615–13,732,346, 14 genes, copy number 11–21 (within-gene range 2–21): AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA.
- chr11:23,370,116–23,431,799, 4 genes, copy number 16: AC100767.2, WIZP1, MIR8054, AC100767.1.
- chr11:29,159,956–32,343,409, 41 genes, copy number 5–23: AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4, AL035078.1, AL035078.3, AL035078.2, U3, EIF4A2P5, RCN1, AL078612.1, THEM7P, AL078612.2.
- chr11:33,256,672–35,918,739, 52 genes, copy number 24–40 (within-gene range 3–40): HIPK3, KIAA1549L, AL137161.1, AL133399.1, AL049629.1, C11orf91, AL049629.2, CD59, FBXO3, FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1, AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1.
- chr11:35,967,010–35,997,675, 3 genes, copy number 28: AL136146.1, AL136146.2, RPL12P31.
- chr11:43,063,637–49,434,438, 195 genes, copy number 5–6 (broad region; genes not listed).
- chr11:128,095,758–130,476,641, 42 genes, copy number 5: LINC02725, LINC02098, ETS1, MIR6090, ETS1-AS1, AP001122.1, FLI1, SENCR, KCNJ1, AP000920.1, KCNJ5, C11orf45, TP53AIP1, ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P, BARX2, RPS27P20, AP003500.1, LINC01395, AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8, ADAMTS15.
- chr12:55,009,746–55,030,017, 2 genes, copy number 59: AC027287.2, NEUROD4.
- chr12:57,674,665–57,846,729, 21 genes, copy number 30: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2.
- chr12:64,146,388–64,397,065, 7 genes, copy number 49 (within-gene range 3–49): AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2.
- chr12:65,830,750–65,882,167, 2 genes, copy number 40 (within-gene range 3–40): AC107308.1, HMGA2-AS1.
- chr12:68,805,011–70,243,379, 33 genes, copy number 49 (within-gene range 3–49): AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1.
- chr12:70,443,784–70,543,040, 2 genes, copy number 27 (within-gene range 3–27): RNU4-65P, AC025569.1.
- chr12:70,638,073–70,920,738, 2 genes, copy number 50 (within-gene range 3–50): PTPRR, FAHD2P1.
- chr12:71,709,171–71,800,286, 3 genes, copy number 35–57: AC011601.1, RAB21, AC089984.1.
- chr12:76,137,425–76,348,415, 5 genes, copy number 49: AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10.
- chr12:80,343,515–81,759,553, 18 genes, copy number 43 (within-gene range 3–43): RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1.
- chr12:81,953,719–82,479,239, 5 genes, copy number 19–50: LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3.
- chr12:84,154,434–89,526,262, 51 genes, copy number 11–82 (within-gene range 3–82): AC090679.2, AC087888.1, AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C, AC016993.1, AC139697.1, AC010196.1, AC079597.1, RPL23AP68, AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3, RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3, Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1, LINC02458, AC006199.1, RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4.
- chr12:90,905,622–91,005,026, 3 genes, copy number 38 (within-gene range 3–38): CCER1, LINC00615, EPYC.
- chr12:95,657,807–95,858,839, 4 genes, copy number 36–46 (within-gene range 3–46): NTN4, AC090001.1, RNU6-247P, LINC02410.
- chr12:96,101,951–96,400,480, 8 genes, copy number 42: RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1.
- chr12:97,150,081–97,160,538, 2 genes, copy number 24 (within-gene range 3–24): AC007656.3, AC007656.4.
- chr12:100,267,140–100,422,055, 2 genes, copy number 50 (within-gene range 3–50): SCYL2, SLC17A8.
- chr12:103,079,634–103,179,247, 2 genes, copy number 35 (within-gene range 3–35): AC068643.1, AC068643.2.
- chr12:116,368,764–116,603,585, 7 genes, copy number 20 (within-gene range 3–20): AC079384.1, MIR4472-2, LINC02457, LINC00173, MAP1LC3B2, AC125603.4, AC125603.3.
- chr19:28,294,093–29,233,385, 25 genes, copy number 30 (within-gene range 3–30): AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P.
- chr19:29,775,504–31,349,436, 23 genes, copy number 37: AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791.
- chr19:37,401,404–37,469,275, 2 genes, copy number 43 (within-gene range 2–43): AC008806.1, ZNF569.
- chr19:37,506,939–37,730,733, 12 genes, copy number 25 (within-gene range 2–25): ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3.
- chr22:19,714,503–22,043,934, 138 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr22:27,276,240–28,008,581, 18 genes, copy number 6: AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1, AL050402.2, AL050402.1, AL133456.1, AL121885.2, AL121885.3, AL121885.1, MN1, PITPNB, TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1.
- chr22:27,994,474–28,056,453, 3 genes, copy number 6: AL033538.1, AL033538.2, RN7SL757P.

Autosomal genes at a single copy (total copy number 1): 1,846. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
